Somatic mutation profile of tumor specimen TCGA-DI-A1NN-01A (aliquot TCGA-DI-A1NN-01A-11D-A16D-09) from TCGA case TCGA-DI-A1NN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.0 years (23,026 days).
Specimen TCGA-DI-A1NN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96c41fc1-c43d-4582-a4d6-60508ea7ed8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DI-A1NN-11A (Solid Tissue Normal), aliquot TCGA-DI-A1NN-11A-21D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b3487b6-5066-454e-829c-2ce743f4ad54

The open-access MAF lists 65 somatic variants for this specimen: 43 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 36, Silent 22, Nonsense Mutation 4, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.670C>T p.R224* (on ENST00000281708 / NM_001349798.2; = p.R144* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 71/156 reads (46%) | hotspot (GDC flag); catalogued as rs1406877044, COSV55899023; called by muse, mutect2, varscan2
- OCRL | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853263, CM050304, COSV63980555; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 110/146 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64110036; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4007G>T p.R1336I | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV54461766, COSV99716284; called by muse, mutect2, varscan2
- AHNAK | c.14926A>T p.K4976* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV57224987; called by muse, mutect2, varscan2
- ANKRD30A | c.1681T>G p.Y561D (on ENST00000611781; = p.Y505D on NM_052997.2) | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370765794, COSV64617219; called by muse, mutect2, varscan2
- BRD3 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV57705561; called by muse, mutect2, varscan2
- CEP290 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV58354512; called by muse, mutect2, varscan2
- CHD5 | c.4370G>A p.R1457Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1416194984, COSV52421984; called by muse, mutect2, varscan2
- COL7A1 | c.4342G>A p.G1448S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60400776; called by muse, mutect2, varscan2
- CPSF2 | c.10A>G p.I4V | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.263); catalogued as rs777562704, COSV54100089; called by muse, mutect2, varscan2
- CSMD2 | c.8239C>T p.R2747C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs933232480, COSV53945050; called by muse, mutect2, varscan2
- DCAF4L2 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV60481189; called by muse, mutect2, varscan2
- DDX3X | c.593G>C p.R198P (on ENST00000399959; = p.R199P on NM_001356.5) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV67864226; called by muse, mutect2, varscan2
- DPRX | c.548G>T p.C183F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.162); catalogued as COSV64949895; called by muse, mutect2
- EIF4G2 | c.1326G>C p.Q442H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60598531; called by muse, mutect2, varscan2
- ERAL1 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs112005054, COSV54740667; called by muse, mutect2, varscan2
- FAM47A | c.689C>G p.T230S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV60498999; called by muse, mutect2, varscan2
- GATB | c.1104G>C p.Q368H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV56132492; called by muse, mutect2, varscan2
- GNPTAB | c.3589G>A p.E1197K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV73418393; called by muse, varscan2
- GSTA5 | c.465G>A p.W155* | Nonsense Mutation (SNP) | VAF 19/112 reads (17%) | catalogued as COSV52863566; called by muse, mutect2, varscan2
- HDAC6 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as rs1250912295, COSV61930071; called by muse, mutect2, varscan2
- HMX2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV60593251; called by muse, mutect2, varscan2
- MUC16 | c.37859T>C p.L12620P | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV67483318; called by muse, mutect2
- MUC5B | c.12323C>T p.S4108L | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs374548199; called by muse, mutect2, varscan2
- MYO5A | c.1668+1G>A p.X556_splice | Splice Site (SNP) | VAF 22/67 reads (33%) | catalogued as COSV62559513; called by muse, mutect2, varscan2
- MYOF | c.5263A>G p.I1755V | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV63708655; called by muse, mutect2, varscan2
- NOL4 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as COSV52356499; called by muse, mutect2, varscan2
- OR2J2 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV65848300; called by muse, mutect2, varscan2
- OR6C1 | c.188A>T p.N63I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV65574261, COSV65574551; called by muse, mutect2, varscan2
- PCDHB2 | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV50608943; called by muse, mutect2, varscan2
- PHC2 | c.1041A>T p.Q347H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57106710; called by muse, mutect2
- QSER1 | c.4032_4034del p.E1344del (on ENST00000399302; = p.E1473del on NM_001076786.3) | In Frame Del (DEL) | VAF 18/79 reads (23%) | catalogued as rs755802143; called by pindel, varscan2
- RHOXF2B | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs782660989, COSV65054915; called by muse, mutect2, varscan2
- SI | c.4511G>C p.R1504P | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as COSV52266598, COSV52293282; called by muse, mutect2
- SPOCK3 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV62732879; called by muse, mutect2, varscan2
- UPRT | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV64920471; called by muse, mutect2
- WNT8A | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753201379, COSV64231401; called by muse, mutect2, varscan2
- ZMYM3 | c.2794A>G p.I932V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV58739892; called by muse, mutect2
- ZNF831 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV64043680, COSV64046024; called by muse, mutect2, varscan2
- CTNND1 | c.1641_1644dup p.R549Tfs*5 | Frame Shift Ins (INS) | VAF 31/50 reads (62%) | called by mutect2, pindel, varscan2
- CACNA1B | c.1575C>T p.F525= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV53141453; called by muse, mutect2
- CD163L1 | c.2265G>A p.S755= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs927645840, COSV58016797; called by muse, mutect2, varscan2
- CEP68 | c.690G>A p.P230= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs747933628, COSV53126816; called by muse, mutect2, varscan2
- ERBB4 | c.2157G>A p.K719= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV53566972, COSV53572250; called by muse, mutect2, varscan2
- ESR1 | c.1344C>G p.L448= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as COSV52780820; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2808C>T p.L936= (on ENST00000265755 / NM_016328.3; = p.L921= on NM_005685.4) | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as rs1486355855, COSV56086736; called by muse, mutect2, varscan2
- IGSF9B | c.2700G>C p.L900= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV58071169; called by muse, mutect2, varscan2
- IMPDH2 | c.195G>T p.L65= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV58708732; called by muse, mutect2, varscan2
- KANK1 | c.3615C>T p.L1205= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs199537812, COSV66528752; called by muse, mutect2, varscan2
- MAS1 | c.600G>A p.T200= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs771015772, COSV53121939; called by muse, mutect2, varscan2
- MEI1 | c.2457C>A p.T819= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV55905953; called by muse, mutect2, varscan2
- PASK | c.999C>T p.S333= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs746467097, COSV52157967; called by muse, mutect2, varscan2
- PCDHB5 | c.1494C>T p.R498= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV50662610; called by muse, mutect2, varscan2
- RNF213 | c.8553C>T p.D2851= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV60405635; called by muse, mutect2, varscan2
- RYR2 | c.5298C>A p.P1766= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV63704465; called by mutect2, varscan2
- SHC3 | c.1137T>C p.Y379= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs1240104367, COSV65440056; called by muse, mutect2, varscan2
- SLITRK5 | c.1965C>A p.G655= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs751823416, COSV61525053, COSV61526488; called by muse, mutect2, varscan2
- SORBS2 | c.2850C>T p.N950= (on ENST00000284776 / NM_021069.5; = p.N516= on NM_003603.6) | Silent (SNP) | VAF 46/163 reads (28%) | catalogued as COSV53010581; called by muse, mutect2, varscan2
- TCERG1L | c.720C>T p.I240= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1002127081, COSV64054636; called by muse, mutect2, varscan2
- UPRT | c.771T>C p.H257= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs138018564, COSV64920465; called by muse, mutect2
- USP11 | c.1257G>A p.V419= (on ENST00000218348; = p.V376= on NM_001371072.1) | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV54475285; called by muse, mutect2, varscan2
- ZNF81 | c.1563T>C p.T521= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV58577758; called by muse, mutect2, varscan2
